Gene-level copy-number profile of tumor specimen TCGA-GN-A26D-06A from TCGA case TCGA-GN-A26D, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 74.6 years (27,251 days).
Specimen TCGA-GN-A26D-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.25d87a44-add0-43b9-8776-0f12123722d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A26D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/556e63c7-00d0-49bb-bf2c-0d78f70d6312

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 644; copy number 2: 15,125; copy number 3: 16,510; copy number 4: 24,019; copy number 5: 2,079; copy number 6: 368; copy number 7: 58; copy number 8: 27; copy number 9: 396; copy number 10: 13; copy number 11: 54; copy number 12: 1; copy number 13: 13; copy number 14: 37; copy number 15: 30; copy number 16: 27; copy number 17: 104; copy number 18: 48; copy number 19: 31; copy number 20: 1; copy number 22: 11; copy number 23: 37; copy number 25: 2; copy number 26: 35; copy number 29: 5; copy number 31: 2; copy number 33: 7; copy number 34: 71; copy number 35: 4; copy number 36: 1; copy number 39: 9; copy number 40: 31; copy number 46: 16.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A26D-06A-11D-A192-01): tumor purity 0.78, ploidy 3.19, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 913 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:795,606–1,295,068, 17 genes, copy number 15 (within-gene range 4–15): ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT.
- chr5:2,921,496–3,536,094, 4 genes, copy number 9–15 (within-gene range 3–15): AC094105.2, LINC01377, LINC01019, LINC02162.
- chr5:7,344,579–7,391,907, 5 genes, copy number 10: AC027343.3, LINC02123, AC027343.1, AC027343.2, LINC02142.
- chr5:13,144,000–13,638,381, 4 genes, copy number 13–23: AC016553.1, RPS23P5, NENFP3, AC016546.1.
- chr5:14,704,800–14,877,919, 7 genes, copy number 18 (within-gene range 3–18): ANKH, AC010491.2, RBBP4P1, MIR4637, AC016575.1, UQCRBP3, HNRNPKP5.
- chr5:37,811,589–38,608,354, 16 genes, copy number 9–17 (within-gene range 6–17): GDNF-AS1, GDNF, LINC02117, AC008869.1, LINC02110, AC034226.1, LINC02119, AC010338.1, EGFLAM, EGFLAM-AS4, EGFLAM-AS3, EGFLAM-AS2, EGFLAM-AS1, AC091839.1, AC010457.1, LIFR.
- chr5:41,306,952–41,587,787, 2 genes, copy number 9–17 (within-gene range 8–20): PLCXD3, AC008817.1.
- chr11:56,699,095–56,703,884, 1 gene, copy number 15: OR9G1.
- chr11:58,023,881–59,058,659, 49 genes, copy number 17 (within-gene range 5–17): OR9Q1, RNU6-899P, OR6Q1, VN2R9P, AP004247.2, AP004247.1, OR9L1P, OR9I3P, OR9I1, OR9I2P, OR5BL1P, OR9Q2, OR1S2, OR1S1, OR10Q1, EIF4A2P3, OR10W1, OR10Q2P, OR5BC1P, OR5B19P, OR5B10P, AP000435.1, OR5B17, OR5B1P, OR5B15P, OR5B3, OR5B2, OR5B12, AP003557.2, AP003557.1, OR5B21, LPXN, ZFP91, ZFP91-CNTF, AP001350.1, CNTF, AP001350.2, GLYAT, AP000445.1, AP000445.2, TMA16P1, GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1.
- chr11:76,137,315–79,612,300, 75 genes, copy number 22–34 (broad region; genes not listed).
- chr11:80,321,620–81,556,425, 9 genes, copy number 39: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25.
- chr11:99,120,176–99,120,490, 1 gene, copy number 36: RN7SKP53.
- chr11:100,687,288–102,683,913, 31 genes, copy number 40 (within-gene range 2–40): ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2, MMP7, MMP20, AP000851.1, AP000851.2.
- chr11:103,109,410–104,609,498, 16 genes, copy number 46 (within-gene range 2–46): DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552.
- chr11:113,314,579–113,475,691, 6 genes, copy number 31–35: TTC12, AP002840.2, ANKK1, AP002840.1, DRD2, MIR4301.
- chr11:113,859,346–114,356,571, 7 genes, copy number 34 (within-gene range 2–34): RNU6-1107P, HTR3B, HTR3A, ZBTB16, AP002755.1, AP002518.2, NNMT.
- chr11:114,512,706–114,707,069, 7 genes, copy number 33: NXPE2P1, AC020549.3, NXPE1, AC020549.1, NXPE4, AC020549.2, NXPE2.
- chr12:32,679,200–32,896,777, 12 genes, copy number 16: DNM1L, AC084824.2, Y_RNA, AC084824.5, AC084824.1, YARS2, AC084824.3, AC084824.4, AC087588.2, PKP2, AC087588.1, RPL35AP27.
- chr12:45,215,987–45,440,404, 1 gene, copy number 19 (within-gene range 2–19): ANO6.
- chr12:45,444,766–45,445,438, 1 gene, copy number 19: AC063924.1.
- chr12:55,113,077–55,263,431, 8 genes, copy number 10: OR9K1P, AC027287.1, OR9K2, OR9R1P, OR10U1P, OR10A7, OR6C74, OR6C69P.
- chr12:56,588,518–56,874,268, 14 genes, copy number 17: RNU6-343P, BAZ2A, ATP5F1B, SNORD59A, PTGES3, RN7SL809P, NACA, AC117378.1, PRIM1, HSD17B6, AC121758.2, AC121758.4, AC121758.3, AC121758.1.
- chr12:57,194,504–59,789,855, 78 genes, copy number 11–29 (within-gene range 3–29) (broad region; genes not listed).
- chr12:60,363,822–60,419,293, 2 genes, copy number 15: AC090022.1, AC090022.2.
- chr12:61,600,067–61,702,771, 2 genes, copy number 9: DUX4L52, AC090629.1.
- chr12:61,775,923–61,776,400, 1 gene, copy number 9: RPL21P104.
- chr12:63,558,913–63,823,895, 8 genes, copy number 19: DPY19L2, AC084357.2, AC027667.1, AC084357.3, AC084357.1, RXYLT1, RXYLT1-AS1, PABPC1P4.
- chr12:63,871,739–63,888,598, 3 genes, copy number 19: RPL36AP41, AC079866.2, AC079866.1.
- chr12:64,404,392–68,576,136, 92 genes, copy number 14–26 (broad region; genes not listed).
- chr12:68,805,011–69,460,724, 20 genes, copy number 15–17: AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373.
- chr12:69,608,564–70,243,379, 11 genes, copy number 26: LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2.
- chr12:70,443,784–70,443,923, 1 gene, copy number 26: RNU4-65P.
- chr12:70,638,073–71,032,083, 4 genes, copy number 13: PTPRR, FAHD2P1, Y_RNA, AC123905.1.
- chr12:72,249,964–72,276,954, 1 gene, copy number 16: TRHDE-AS1.
- chr12:75,926,213–76,084,735, 9 genes, copy number 9: AC011611.6, RN7SL734P, AC011611.2, AC011611.1, PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5.
- chr12:77,129,178–77,163,638, 1 gene, copy number 12: AC079030.1.
- chr18:47,390–673,578, 21 genes, copy number 9: TUBB8B, AP001005.3, IL9RP4, AP001005.2, ROCK1P1, MIR8078, USP14, THOC1, AP000845.1, AP000915.1, COLEC12, AP000915.2, LINC01925, CETN1, RN7SKP146, CLUL1, AP001178.4, TYMSOS, AP001178.3, AP001178.1, TYMS.
- chr18:721,588–15,330,282, 353 genes, copy number 9 (within-gene range 3–9) (broad region; genes not listed).
- chr21:17,513,043–17,593,579, 1 gene, copy number 16 (within-gene range 4–16): CXADR.
- chr21:17,527,140–17,894,485, 11 genes, copy number 16: Y_RNA, Y_RNA, BTG3, BTG3-AS1, AP000432.1, AP000432.2, C21orf91-OT1, C21orf91, AL109761.1, CHODL-AS1, RPL37P3.

Autosomal genes at a single copy (total copy number 1): 644. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
